Somatic mutation profile of tumor specimen TCGA-EL-A4KI-01A (aliquot TCGA-EL-A4KI-01A-11D-A257-08) from TCGA case TCGA-EL-A4KI, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 63.5 years (23,182 days).
Specimen TCGA-EL-A4KI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a44a01ee-6032-4857-9fb8-04b10b534363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4KI-10A (Blood Derived Normal), aliquot TCGA-EL-A4KI-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b4249f1-71c6-43ce-9a4e-27a3090f4990

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 99/150 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EFCAB5 | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV57932421; called by muse, mutect2, varscan2
- GABRA2 | c.46del p.V16Ffs*59 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs1410992303; called by mutect2, pindel, varscan2
- GCN1 | c.1331A>T p.H444L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs746494905, COSV56110130; called by muse, mutect2, varscan2
- IGSF9B | c.1200C>A p.Y400* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58066559, COSV58069540; called by muse, mutect2, varscan2
- KCTD2 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59369101; called by muse, mutect2, varscan2
- KIAA0930 | c.382G>A p.G128R (on ENST00000336156 / NM_001009880.2; = p.G133R on NM_015264.2) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.806); catalogued as rs767416805, COSV52662530, COSV52663981; called by muse, mutect2, varscan2
- PKP4 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV67677926; called by muse, mutect2, varscan2
- RB1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57313458; called by muse, mutect2, varscan2
- SLC47A1 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as rs185769986, COSV54502090; called by muse, mutect2, varscan2
- SLITRK1 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV65676536; called by muse, mutect2, varscan2
- SRRM2 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV57075918; called by muse, mutect2, varscan2
- TAF2 | c.2345A>G p.N782S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65419029; called by muse, mutect2
- TTN | c.9769C>T p.R3257C (on ENST00000591111; = p.R3211C on NM_003319.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs374521620, COSV60158956; called by muse, mutect2, varscan2
- WNT11 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs200871564; called by muse, mutect2
- RP1L1 | c.5594G>A p.G1865E | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.7368C>T p.D2456= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs979343566, COSV56472944; called by muse, mutect2, varscan2
- ECSIT | c.231G>A p.G77= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs759999123, COSV52939902; called by muse, mutect2, varscan2
